Somatic mutation profile of tumor specimen MP2PRT-PARCPB-TMP1-A (aliquot MP2PRT-PARCPB-TMP1-A-1-0-D-A83N-36) from MP2PRT case MP2PRT-PARCPB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Blood; Age at diagnosis: 4.6 years (1,678 days).
Specimen MP2PRT-PARCPB-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6631cee6-594f-4b69-825b-9273b47771ca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARCPB-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARCPB-NM1-A-1-0-D-A83N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1fffdcec-62bb-4762-b582-c405cda36b4f

The open-access MAF lists 10 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 9, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 34/491 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs397507511, CM030493, COSV61004768, COSV61009351; ClinVar: likely pathogenic; called by muse, mutect2
- KCMF1 | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 32/507 reads (6%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.046); catalogued as rs375040118; called by muse, mutect2
- KIAA1755 | c.334C>A p.Q112K | Missense Mutation (SNP) | VAF 20/432 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.024); catalogued as rs1442915821; called by muse, mutect2
- NEDD4 | c.2828G>T p.R943I (on ENST00000508342 / NM_001284338.1; = p.R524I on NM_006154.4) | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV59063692; called by muse, mutect2
- EFCAB5 | c.642G>T p.L214F | Missense Mutation (SNP) | VAF 12/317 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FREM2 | c.524T>C p.V175A | Missense Mutation (SNP) | VAF 40/524 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2
- FSCB | c.1604C>A p.A535E | Missense Mutation (SNP) | VAF 32/354 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.118); called by muse, mutect2
- STON2 | c.2009T>A p.L670Q (on ENST00000649389 / NM_001366849.2; = p.L613Q on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 128/340 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- UPF1 | c.1804G>T p.D602Y (on ENST00000599848 / NM_001297549.2; = p.D591Y on NM_002911.4) | Missense Mutation (SNP) | VAF 16/314 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- KIDINS220 | c.5124T>A p.T1708= | Silent (SNP) | VAF 21/525 reads (4%) | called by muse, mutect2
